Somatic mutation profile of tumor specimen C3N-03015-01 (aliquot CPT0245180009) from CPTAC case C3N-03015, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 61.0 years (22,292 days).
Specimen C3N-03015-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade8b157-3dd9-451e-809f-42611df62d38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03015-31 (Blood Derived Normal), aliquot CPT0245220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1516f7ae-1fd2-431c-99b4-5dce9d500862

The open-access MAF lists 229 somatic variants for this specimen: 166 protein-altering or splice-affecting, 38 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 38, Intron 16, Nonsense Mutation 11, Frame Shift Ins 4, Splice Region 3, Frame Shift Del 3, 3'Flank 3, In Frame Del 2, 5'Flank 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C10 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 42/443 reads (9%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV60797088; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 44/196 reads (22%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- VDR | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 50/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121909793, CM900226; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM28 | c.2058C>G p.I686M | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs751029250; called by muse, mutect2
- AOX1 | c.3583del p.I1195* | Frame Shift Del (DEL) | VAF 22/133 reads (17%) | catalogued as COSV53495489; called by mutect2, pindel, varscan2
- APOBEC3D | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as rs1443766610, COSV99329187; called by muse, mutect2, varscan2
- APOC4-APOC2 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.821); catalogued as rs764950395; called by muse, mutect2, varscan2
- ATP7B | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM053794; called by muse, mutect2, varscan2
- BCLAF3 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV61413453; called by muse, mutect2, varscan2
- BIRC3 | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54815819; called by muse, mutect2, varscan2
- BMP8B | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735594; called by muse, mutect2
- C11orf21 | c.298C>T p.P100S (on ENST00000381153 / NM_001329958.2; = p.P146S on NM_001142946.3) | Missense Mutation (SNP) | VAF 70/710 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as rs1195485166; called by muse, mutect2
- CCDC178 | c.1559A>T p.E520V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55757342; called by mutect2, varscan2
- CEBPZ | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.215); catalogued as rs767073685; called by muse, varscan2
- CELSR1 | c.5926C>A p.P1976T | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs780129611; called by muse, mutect2, varscan2
- CYP27C1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1418713591, COSV58866324; called by muse, mutect2, varscan2
- DACT2 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1474044975, COSV64694174; called by muse, varscan2
- DDX23 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.142); catalogued as rs111734006; called by muse, mutect2, varscan2
- DNAH5 | c.2023G>A p.V675I | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV54232739; called by muse, mutect2
- EFHB | c.1319C>G p.S440* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV99041774; called by muse, mutect2, varscan2
- FAM135B | c.3823G>A p.G1275R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374711628; called by muse, mutect2, varscan2
- FAT4 | c.11497G>C p.E3833Q | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.638); catalogued as COSV58701642; called by muse, mutect2, varscan2
- FNDC1 | c.3881C>G p.P1294R | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs769296623, COSV99797116; called by muse, mutect2
- FPGT-TNNI3K | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100598567; called by muse, mutect2
- GFRA3 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs80086291; called by muse, mutect2, varscan2
- IL17RC | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 85/405 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs553003266; called by muse, mutect2, varscan2
- JCAD | c.3263G>A p.R1088K | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs985700689, COSV64762179; called by muse, mutect2, varscan2
- KCNT2 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV54063549; called by muse, mutect2, varscan2
- KHDRBS2 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs148769298; called by muse, mutect2, varscan2
- KLHL26 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV56316834; called by muse, mutect2, varscan2
- LAMA1 | c.8963G>A p.R2988H | Missense Mutation (SNP) | VAF 48/750 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs546562151, COSV67533085; called by muse, mutect2
- LEXM | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs141829608; called by muse, mutect2, varscan2
- MED13L | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 103/504 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV56122751; called by muse, mutect2, varscan2
- MEGF6 | c.4412C>T p.P1471L | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1470608752; called by muse, mutect2, varscan2
- NFE2L3 | c.1375C>A p.H459N | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as COSV50227181; called by muse, mutect2, varscan2
- NUP205 | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762416724; called by muse, mutect2
- OR13C3 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV66165854; called by muse, mutect2, varscan2
- OSGEP | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs369612242; called by muse, mutect2
- PGBD5 | c.892C>T p.R298C (on ENST00000525115; = p.R367C on NM_001258311.2) | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1327319064, COSV58412896; called by muse, mutect2, varscan2
- PKHD1 | c.10555C>A p.L3519M | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV64388077; called by muse, mutect2
- PLPPR4 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs754693317, COSV64564446; called by muse, mutect2, varscan2
- PPFIBP2 | c.2391G>A p.M797I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201706133; called by muse, mutect2, varscan2
- PPOX | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV57086561; called by muse, mutect2, varscan2
- PPOX | c.1292-6T>C | Splice Region (SNP) | VAF 93/901 reads (10%) | catalogued as rs752418780; called by muse, mutect2, varscan2
- PYURF | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs781138762; called by muse, mutect2, varscan2
- RPS6KC1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs763853562; called by muse, mutect2
- SAMD9L | c.4121dup p.P1375Afs*5 | Frame Shift Ins (INS) | VAF 45/193 reads (23%) | catalogued as rs1033729089; called by mutect2, pindel, varscan2
- SLC52A3 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs201100567; called by muse, mutect2, varscan2
- SLC6A20 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755132088; called by muse, mutect2, varscan2
- SPPL2C | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs774363885, COSV61291952; called by muse, mutect2, varscan2
- SSC5D | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs990320096; called by muse, mutect2
- TAB3 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV55841479; called by muse, mutect2, varscan2
- THOC1 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.398); catalogued as COSV99863491; called by muse, mutect2, varscan2
- THTPA | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs755628048; called by muse, mutect2
- TTN | c.10738G>T p.D3580Y (on ENST00000591111; = p.D3534Y on NM_003319.4) | Missense Mutation (SNP) | VAF 44/236 reads (19%) | catalogued as rs1300532206, COSV100590574; called by muse, mutect2, varscan2
- VWA8 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375266930; called by muse, mutect2, varscan2
- VWCE | c.2474C>T p.S825L | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs150720177; called by muse, mutect2, varscan2
- WDR24 | c.1660C>T p.R554W (on ENST00000248142; = p.R424W on NM_032259.4) | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs151322294; called by muse, mutect2, varscan2
- ZFHX3 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.318); catalogued as rs1187392987; called by muse, mutect2
- ZFPM1 | c.2397G>C p.K799N | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60320405; called by muse, mutect2, varscan2
- ZNF101 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as rs375316779, COSV58908794; called by muse, mutect2, varscan2
- ZNF572 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs748400507, COSV60002752; called by muse, mutect2, varscan2
- ADAM17 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- AGTR1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AMBRA1 | c.2480C>G p.P827R (on ENST00000458649 / NM_001367468.1; = p.P737R on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ANKRD11 | c.4673C>T p.S1558F | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- AP1M2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ARHGAP28 | c.1341G>A p.W447* (on ENST00000383472 / NM_001366230.1; = p.W288* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- ARID2 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.1); called by muse, mutect2
- ARL13B | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- BBOX1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- BRAF | c.2227G>C p.E743Q (on ENST00000288602 / NM_001374244.1; = p.E703Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- BRMS1 | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 83/325 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- C1orf141 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CC2D1A | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- CCDC150 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- CENPE | c.3979G>C p.E1327Q | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- CENPI | c.1165T>C p.Y389H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHD6 | c.2747A>G p.E916G | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL11A2 | c.299T>A p.L100H | Missense Mutation (SNP) | VAF 84/723 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL15A1 | c.3153G>A p.M1051I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- COL1A1 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL5A3 | c.2705_2707del p.G902del | In Frame Del (DEL) | VAF 12/78 reads (15%) | called by pindel, varscan2
- CSMD3 | c.2918T>G p.F973C (on ENST00000297405 / NM_001363185.1; = p.F869C on NM_052900.3) | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK2A2 | c.492G>C p.M164I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2
- CTNNB1 | c.395_437del p.L132Qfs*11 | Frame Shift Del (DEL) | VAF 78/388 reads (20%) | called by mutect2, pindel
- CTTNBP2 | c.3549dup p.V1184Sfs*7 | Frame Shift Ins (INS) | VAF 10/94 reads (11%) | called by mutect2, pindel
- CTTNBP2 | c.2299G>C p.E767Q | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- CYFIP1 | c.210C>G p.N70K | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- DNAH8 | c.7079C>G p.A2360G | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2
- EFTUD2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELN | c.2184A>T p.G728= (on ENST00000320399 / NM_001278939.1; = p.G695= on NM_000501.4) | Splice Region (SNP) | VAF 43/374 reads (11%) | called by muse, mutect2, varscan2
- FAT2 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- FSIP2 | c.19115del p.N6372Tfs*7 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- GABRA6 | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- GAR1 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.18); called by muse, mutect2
- GSPT1 | c.977_979dup p.I326_C327insF (on ENST00000420576 / NM_001130007.2; = p.I464_C465insF on NM_002094.4) | In Frame Ins (INS) | VAF 36/184 reads (20%) | called by mutect2, pindel, varscan2
- HELZ2 | c.2060G>A p.G687D (on ENST00000467148 / NM_001037335.2; = p.G118D on NM_033405.3) | Missense Mutation (SNP) | VAF 36/425 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- HFE | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 65/287 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HMGXB3 | c.4072C>G p.L1358V (on ENST00000613459; = p.L1112V on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HSPG2 | c.5849T>C p.V1950A | Missense Mutation (SNP) | VAF 60/652 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGKV3D-20 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 139/1051 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- INKA2 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2
- INSL6 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 52/492 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2
- KCNMA1 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 53/510 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNQ4 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- KITLG | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KRTAP2-3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- LAT2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- LYSMD3 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAGEA8 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MBLAC1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MDM1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.085); called by muse, mutect2
- MGAM2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MRPL39 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- MUC19 | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- NANS | c.494dup p.M165Ifs*29 | Frame Shift Ins (INS) | VAF 86/319 reads (27%) | called by mutect2, pindel, varscan2
- NELL2 | c.969T>G p.D323E | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NMU | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2
- NUDT9 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP188 | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP205 | c.2316G>T p.L772F | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2G6 | c.293T>G p.V98G | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- OR51I1 | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2
- OSMR | c.2339G>C p.S780T | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCED1A | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.7694C>G p.S2565C | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PDCD11 | c.2699A>T p.D900V | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIK3C2A | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2
- PTRH1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PZP | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RAB3IP | c.427G>T p.A143S (on ENST00000550536 / NM_175623.4; = p.A127S on NM_022456.5) | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBBP8 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 120/537 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM26 | c.2979T>A p.D993E (on ENST00000438737 / NM_001366735.2; = p.D966E on NM_022118.5) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); called by muse, mutect2
- REV3L | c.1324A>T p.N442Y | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- RPS6KA5 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2
- SCAP | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SEMA4C | c.1749G>T p.L583F | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SERPINI2 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, varscan2
- SFI1 | c.3197G>A p.S1066N (on ENST00000400288 / NM_001007467.3; = p.S1035N on NM_014775.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.382); called by muse, mutect2
- SLC16A12 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC7A6 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SMG7 | c.2440A>G p.M814V | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX4 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); called by muse, mutect2
- SP110 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.313); called by muse, mutect2
- SP8 | c.463G>C p.G155R (on ENST00000361443 / NM_198956.4; = p.G173R on NM_182700.6) | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- STEAP2 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SUPT16H | c.2437A>T p.S813C | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SV2B | c.1580A>C p.H527P | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SYNRG | c.1925C>A p.S642* | Nonsense Mutation (SNP) | VAF 43/226 reads (19%) | called by muse, mutect2, varscan2
- TAPBPL | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TP53BP1 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2
- TPO | c.815T>A p.I272K | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAPPC10 | c.1173dup p.A392Cfs*21 | Frame Shift Ins (INS) | VAF 16/140 reads (11%) | called by mutect2, varscan2
- TRIM10 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- TRIM37 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.417); called by muse, mutect2
- TTN | c.92843C>A p.S30948Y (on ENST00000591111; = p.S23524Y on NM_003319.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | PolyPhen probably damaging (0.998); called by muse, varscan2
- VEPH1 | c.2155A>G p.I719V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- WDR54 | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- YEATS2 | c.2185A>T p.K729* | Nonsense Mutation (SNP) | VAF 28/230 reads (12%) | called by mutect2, varscan2
- YME1L1 | c.1240G>C p.G414R (on ENST00000326799 / NM_139312.3; = p.G357R on NM_014263.4) | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFHX4 | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF23 | c.1068C>G p.S356R | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- ZNF350 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ZNF600 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZSWIM6 | c.395_415del p.G132_G138del | In Frame Del (DEL) | VAF 57/247 reads (23%) | called by mutect2, pindel
- ABTB2 | c.180C>A p.S60= | Silent (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- AC005833.1 | c.1590G>T p.L530= | Silent (SNP) | VAF 45/233 reads (19%) | called by muse, mutect2, varscan2
- ALS2CL | c.2493C>T p.D831= | Silent (SNP) | VAF 22/199 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF19 | c.1599A>C p.T533= | Silent (SNP) | VAF 32/126 reads (25%) | called by muse, mutect2, varscan2
- ATP2B4 | c.1236C>T p.I412= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs752969528, COSV100397528; called by muse, mutect2, varscan2
- BCHE | c.748C>T p.L250= | Silent (SNP) | VAF 25/158 reads (16%) | called by muse, mutect2, varscan2
- CACTIN | c.507G>A p.R169= | Silent (SNP) | VAF 89/599 reads (15%) | called by muse, mutect2, varscan2
- CHRNA3 | c.1302C>G p.L434= | Silent (SNP) | VAF 41/235 reads (17%) | called by muse, mutect2, varscan2
- CLCN5 | c.168C>T p.S56= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs782057466, COSV56583573; called by muse, mutect2, varscan2
- COL11A2 | c.1956C>A p.G652= (on ENST00000341947 / NM_080680.3; = p.G545= on NM_080679.2) | Silent (SNP) | VAF 27/217 reads (12%) | called by muse, mutect2, varscan2
- DGKI | c.315G>A p.E105= | Silent (SNP) | VAF 35/224 reads (16%) | catalogued as rs1461363279; called by muse, mutect2, varscan2
- DRP2 | c.1923C>T p.G641= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- ECHDC3 | c.537C>G p.V179= | Silent (SNP) | VAF 51/503 reads (10%) | called by muse, mutect2, varscan2
- FOXF1 | c.714C>T p.H238= | Silent (SNP) | VAF 45/339 reads (13%) | called by muse, mutect2, varscan2
- GORASP2 | c.177G>A p.L59= | Silent (SNP) | VAF 42/231 reads (18%) | called by muse, mutect2, varscan2
- ICA1L | c.1173C>T p.L391= | Silent (SNP) | VAF 46/447 reads (10%) | catalogued as rs180939445, COSV64173688; called by muse, mutect2, varscan2
- ILDR1 | c.129C>G p.L43= | Silent (SNP) | VAF 34/283 reads (12%) | called by muse, mutect2, varscan2
- MMP24 | c.1803C>T p.N601= | Silent (SNP) | VAF 63/631 reads (10%) | catalogued as rs1205155627, COSV55770128; called by muse, varscan2
- NCAPD2 | c.2403G>A p.L801= | Silent (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- NT5DC3 | c.15G>A p.A5= | Silent (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- PACS2 | c.1224C>T p.S408= | Silent (SNP) | VAF 26/221 reads (12%) | catalogued as rs781905845; called by muse, mutect2, varscan2
- PHF12 | c.618G>C p.L206= | Silent (SNP) | VAF 76/381 reads (20%) | catalogued as COSV52019270; called by muse, mutect2, varscan2
- PIKFYVE | c.4416C>T p.L1472= | Silent (SNP) | VAF 68/296 reads (23%) | catalogued as rs771655040; called by muse, mutect2, varscan2
- PLA2G4C | c.1488T>A p.T496= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- PPFIA1 | c.162G>A p.L54= | Silent (SNP) | VAF 34/797 reads (4%) | catalogued as rs746993453; called by muse, mutect2
- PROX1 | c.2106T>G p.V702= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- PTGER3 | c.1179G>A p.V393= | Silent (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- PTPRJ | c.390C>T p.I130= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs1410926242; called by muse, mutect2
- RLF | c.4701G>A p.V1567= | Silent (SNP) | VAF 62/313 reads (20%) | called by muse, mutect2, varscan2
- RNASEL | c.1278C>T p.H426= | Silent (SNP) | VAF 22/179 reads (12%) | called by muse, mutect2, varscan2
- SHANK2 | c.5457C>T p.N1819= | Silent (SNP) | VAF 19/420 reads (5%) | catalogued as rs781943323; called by muse, mutect2
- SPTBN2 | c.4602G>A p.Q1534= | Silent (SNP) | VAF 21/533 reads (4%) | called by muse, mutect2
- STMND1 | c.510G>A p.E170= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- TADA2A | c.1092C>T p.P364= | Silent (SNP) | VAF 46/258 reads (18%) | called by muse, mutect2, varscan2
- TMEM119 | c.508C>A p.R170= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV67188524; called by muse, mutect2, varscan2
- TNXB | c.3429C>G p.P1143= | Silent (SNP) | VAF 58/602 reads (10%) | catalogued as rs761274803; called by muse, mutect2, varscan2
- TRIM50 | c.54C>A p.I18= | Silent (SNP) | VAF 123/498 reads (25%) | called by muse, mutect2, varscan2
- UBXN10 | c.453C>T p.D151= | Silent (SNP) | VAF 36/428 reads (8%) | catalogued as rs765029383; called by muse, mutect2
- ADAM10 | c.207-9211C>G | Intron (SNP) | VAF 20/130 reads (15%) | catalogued as rs764876021; called by muse, mutect2, varscan2
- AMPH | c.1182+658G>T | Intron (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- APC2 | c.1208-38T>G | Intron (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2
- C10orf90 | c.*16C>G | 3'UTR (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- COL4A3 | c.2881+48G>A | Intron (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
- ETFDH | c.-35G>A | 5'UTR (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- FRS3 | chr6:41780441 A>G | 5'Flank (SNP) | VAF 30/249 reads (12%) | catalogued as rs984530704; called by muse, mutect2, varscan2
- HCK | c.62+1738G>A | Intron (SNP) | VAF 36/231 reads (16%) | catalogued as COSV52940454; called by muse, mutect2, varscan2
- JAZF1 | c.116-28608G>T | Intron (SNP) | VAF 35/205 reads (17%) | catalogued as rs188152684; called by muse, mutect2, varscan2
- LINC00174 | n.3576C>G | RNA (SNP) | VAF 63/326 reads (19%) | called by muse, mutect2, varscan2
- MARF1 | chr16:15643302 C>G | 5'Flank (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- MINDY4 | c.1678-152C>G | Intron (SNP) | VAF 99/381 reads (26%) | called by muse, mutect2, varscan2
- MIR6511A3 | chr16:16371578 C>T | 3'Flank (SNP) | VAF 88/1308 reads (7%) | called by muse, mutect2
- N4BP2L2 | chr13:32442472 C>G | 3'Flank (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- NAALADL2 | c.43+4623C>G | Intron (SNP) | VAF 5/114 reads (4%) | catalogued as rs1179218236; called by muse, mutect2
- PCDHA10 | c.2388+4397G>A | Intron (SNP) | VAF 35/442 reads (8%) | catalogued as rs868966696, COSV56539496; called by muse, mutect2
- PLEKHH3 | c.2013+65C>T | Intron (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- PPP2R5C | c.93+23171G>A | Intron (SNP) | VAF 16/93 reads (17%) | catalogued as rs576069163; called by muse, mutect2, varscan2
- RAB26 | c.*342C>G | 3'UTR (SNP) | VAF 81/432 reads (19%) | called by muse, mutect2, varscan2
- RASA4DP | chr7:102678496 A>C | 3'Flank (SNP) | VAF 20/376 reads (5%) | called by muse, mutect2
- RHOBTB3 | c.228+27G>A | Intron (SNP) | VAF 32/330 reads (10%) | catalogued as rs758888830, COSV66103333; called by muse, mutect2
- SGIP1 | c.1571-939A>C | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2
- TGFA | c.476-866G>T | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99772793; called by muse, mutect2, varscan2
- TGFBR3 | c.246+11067C>G | Intron (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- ZAP70 | c.890-35C>A | Intron (SNP) | VAF 12/70 reads (17%) | called by mutect2, varscan2
